Somatic mutation profile of tumor specimen C3L-00770-01 (aliquot CPT0026650009) from CPTAC case C3L-00770, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 73.3 years (26,769 days).
Specimen C3L-00770-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c95e5f2-9993-4df9-b828-b66f94d54698.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00770-71 (Blood Derived Normal), aliquot CPT0026710002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ed180e5-f32e-4d48-bc25-6e46ee417e12

The open-access MAF lists 1,286 somatic variants for this specimen: 932 protein-altering or splice-affecting, 193 silent, 161 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 752, Silent 193, Nonsense Mutation 143, Intron 79, 3'UTR 24, RNA 23, 5'Flank 17, Splice Region 15, 5'UTR 12, Splice Site 12, Frame Shift Ins 6, 3'Flank 6.

Variants (750 of 1,286; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPM | c.9319C>T p.R3107* | Nonsense Mutation (SNP) | VAF 59/243 reads (24%) | catalogued as rs199422187, CM092387, COSV54123750; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.4852C>T p.R1618* | Nonsense Mutation (SNP) | VAF 81/252 reads (32%) | catalogued as rs762083530, CM983653, COSV53726137; ClinVar: pathogenic; called by muse, varscan2
- CHD8 | c.3733C>T p.R1245* (on ENST00000646647 / NM_001170629.2; = p.R966* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 35/101 reads (35%) | catalogued as rs886041884; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CYP7B1 | c.1162C>T p.R388* | Nonsense Mutation (SNP) | VAF 103/308 reads (33%) | catalogued as rs72554620, CM982052, COSV59581636; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.1645A>C p.N549H | Missense Mutation (SNP) | VAF 131/375 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519045, CM020140, COSV60640393, COSV60650624; ClinVar: likely pathogenic / drug response; called by muse, mutect2, varscan2
- PAK3 | c.1204G>A p.D402N (on ENST00000262836 / NM_001324328.2; = p.D387N on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/198 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1556298136; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 36/101 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV55874903, COSV99836298; called by muse, mutect2, varscan2
- PIK3CA | c.3132T>G p.N1044K | Missense Mutation (SNP) | VAF 33/169 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen possibly damaging (0.63); catalogued as COSV55875087, COSV55897116; called by muse, mutect2, varscan2
- PIK3R1 | c.1042C>T p.R348* (on ENST00000521381 / NM_181523.3; = p.R78* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 49/146 reads (34%) | hotspot (GDC flag); catalogued as rs1057520690, COSV57123475; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 69/241 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 175/514 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 45/122 reads (37%) | catalogued as rs121913296, CM961221, COSV57300832; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RP2 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 139/404 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1556318633, CM033008, CM077334, COSV54460861; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RYR2 | c.13528G>A p.A4510T | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs397516510, CM043079, COSV63693754; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- USH2A | c.10612C>T p.R3538* | Nonsense Mutation (SNP) | VAF 18/270 reads (7%) | catalogued as rs878853413, CM159124, COSV56359453; ClinVar: likely pathogenic; called by muse, mutect2
- USH2A | c.5603T>G p.F1868C | Missense Mutation (SNP) | VAF 111/279 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1553298240, CM1110222; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.2784G>T p.E928D | Missense Mutation (SNP) | VAF 119/338 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.649); catalogued as COSV60915275; called by muse, mutect2, varscan2
- ABCC9 | c.1199C>T p.T400M | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs749786076, COSV53966945; called by muse, mutect2, varscan2
- AC004593.2 | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as rs1169216156, COSV56090056; called by muse, varscan2
- ACOT9 | c.1198G>T p.E400* | Nonsense Mutation (SNP) | VAF 38/103 reads (37%) | catalogued as COSV60537399; called by muse, mutect2, varscan2
- ACSM2B | c.1351G>T p.D451Y | Missense Mutation (SNP) | VAF 42/233 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61657538; called by muse, mutect2, varscan2
- ACSM2B | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs753290502; called by muse, mutect2, varscan2
- ADAM20 | c.849G>T p.K283N | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs573877636; called by muse, mutect2, varscan2
- ADAM29 | c.2087G>A p.R696Q | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.046); catalogued as rs748743733, COSV63659968; called by muse, mutect2, varscan2
- ADAMDEC1 | c.402G>T p.K134N | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1401817128, COSV56474251; called by muse, mutect2, varscan2
- ADAMTS20 | c.993G>T p.K331N | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs370008149, COSV67130141; called by muse, mutect2, varscan2
- ADAMTS3 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750800733, COSV54388911; called by muse, mutect2, varscan2
- ADAP2 | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 43/119 reads (36%) | catalogued as rs199866282, COSV58294906; called by muse, mutect2, varscan2
- ADGRG2 | c.415-1G>T p.X139_splice (on ENST00000379869 / NM_001079858.3; = p.X136_splice on NM_005756.4) | Splice Site (SNP) | VAF 53/150 reads (35%) | catalogued as COSV100491931, COSV61337428; called by muse, mutect2, varscan2
- ADORA3 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 91/295 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs557748857, COSV53985808; called by muse, mutect2, varscan2
- AGXT | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372399525; called by muse, mutect2, varscan2
- AHNAK | c.2494G>A p.V832I | Missense Mutation (SNP) | VAF 103/344 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as rs763058737; called by muse, mutect2, varscan2
- ALDH1A2 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 92/272 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); catalogued as rs201593015; called by muse, mutect2, varscan2
- AMER1 | c.1617C>A p.F539L | Missense Mutation (SNP) | VAF 72/210 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV57656876; called by muse, mutect2, varscan2
- AMIGO2 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV56973669; called by muse, mutect2, varscan2
- AMY2A | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 71/195 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as rs1233637366, COSV101340608; called by muse, mutect2, varscan2
- AMY2A | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs1185757504, COSV70214228; called by mutect2, varscan2
- ANAPC1 | c.3113G>A p.R1038Q | Missense Mutation (SNP) | VAF 100/340 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as rs1485544572; called by muse, mutect2, varscan2
- ANGPTL4 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 169/474 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.029); catalogued as rs557133449, COSV56844285; called by muse, mutect2, varscan2
- ANKRD34B | c.1367C>A p.S456Y | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV58614539; called by muse, mutect2
- ANKRD36 | c.2772dup p.P925Tfs*8 | Frame Shift Ins (INS) | VAF 27/214 reads (13%) | catalogued as rs1380550081; called by mutect2, pindel, varscan2
- ANKRD36 | c.3629C>T p.S1210L | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.163); catalogued as rs753548252, COSV70401219; called by muse, mutect2, varscan2
- ANOS1 | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 98/248 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as rs144586521, CM109049; called by muse, mutect2, varscan2
- APBB1IP | c.997C>A p.L333I | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.709); catalogued as rs796405869; called by muse, mutect2
- APC | c.5582C>A p.S1861Y | Missense Mutation (SNP) | VAF 115/298 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD961780, COSV104379185, COSV57328606; called by muse, mutect2, varscan2
- APOB | c.12117C>A p.F4039L | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV51943949; called by muse, mutect2
- APOB | c.11107C>T p.R3703C | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs777896608, COSV51932917, COSV99266703; called by muse, mutect2, varscan2
- APOL5 | c.780G>T p.K260N | Missense Mutation (SNP) | VAF 39/242 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.054); catalogued as COSV50766491, COSV50768685; called by muse, mutect2, varscan2
- ARHGAP5 | c.2599C>T p.R867* | Nonsense Mutation (SNP) | VAF 48/124 reads (39%) | catalogued as COSV61534297; called by muse, mutect2, varscan2
- ARHGEF10 | c.827C>T p.S276L (on ENST00000398564; = p.S251L on NM_014629.4) | Missense Mutation (SNP) | VAF 113/323 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs144004435; called by muse, mutect2, varscan2
- ARID1A | c.6763G>A p.E2255K | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV61382225, COSV61386272; called by muse, mutect2, varscan2
- ARL6 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs142258123; called by muse, mutect2, varscan2
- ARMC2 | c.2387C>T p.S796L | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.212); catalogued as rs749756077, COSV64549964; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1283T>C p.I428T | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs1443630928, COSV100771927; called by muse, mutect2, varscan2
- ARRDC5 | c.393C>A p.F131L (on ENST00000381781; = p.F117L on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 125/352 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0.19); catalogued as COSV101108306; called by muse, mutect2, varscan2
- ASB14 | c.458C>T p.S153F (on ENST00000389601; = p.S152F on NM_001142733.3) | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67467017; called by muse, mutect2, varscan2
- ASH1L | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 109/326 reads (33%) | catalogued as COSV64205353; called by muse, mutect2, varscan2
- ATM | c.8517C>A p.F2839L | Missense Mutation (SNP) | VAF 79/268 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs767845728, COSV53761498; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP11B | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765171647; called by muse, mutect2, varscan2
- ATP13A5 | c.1255G>A p.V419I | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.181); catalogued as rs775929293; called by muse, mutect2, varscan2
- ATP2B1 | c.3419C>T p.S1140L | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as COSV53803716; called by muse, mutect2, varscan2
- ATP5MF-PTCD1 | c.32A>C p.K11T | Missense Mutation (SNP) | VAF 64/200 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV99461701; called by muse, varscan2
- ATP9B | c.2447T>C p.L816P | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371724027; called by muse, mutect2
- ATRX | c.6301G>T p.E2101* | Nonsense Mutation (SNP) | VAF 83/214 reads (39%) | catalogued as COSV64877827, COSV64882461; called by muse, mutect2, varscan2
- ATRX | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 65/209 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs782664370; called by muse, mutect2, varscan2
- AVPR1B | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.241); catalogued as rs1558185864; called by muse, mutect2, varscan2
- AZIN2 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs746470026, COSV53859536, COSV53859589; called by muse, mutect2, varscan2
- BCAS2 | c.226C>T p.R76* | Nonsense Mutation (SNP) | VAF 29/113 reads (26%) | catalogued as rs775083042; called by muse, mutect2, varscan2
- BCAT1 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 43/170 reads (25%) | catalogued as rs760034705; called by muse, mutect2, varscan2
- BCHE | c.1493G>A p.R498Q | Missense Mutation (SNP) | VAF 64/199 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs559088873, COSV100012603, COSV100013122; called by muse, mutect2, varscan2
- BCL6B | c.1007C>T p.S336L | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs1200522947, COSV53427386; called by muse, mutect2, varscan2
- BLOC1S5 | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 11/75 reads (15%) | catalogued as COSV55241110; called by muse, mutect2, varscan2
- BTN3A2 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 87/246 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV62687464; called by muse, mutect2, varscan2
- C11orf24 | c.76+1G>A p.X26_splice | Splice Site (SNP) | VAF 41/122 reads (34%) | catalogued as rs757298044, COSV100422775; called by muse, mutect2, varscan2
- C11orf54 | c.926C>T p.T309M (on ENST00000331239; = p.T259M on NM_014039.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs552777927, COSV58682555; called by muse, mutect2, varscan2
- C14orf93 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as rs17851131, COSV54440759; called by muse, mutect2, varscan2
- C1orf105 | c.13G>T p.E5* | Nonsense Mutation (SNP) | VAF 50/138 reads (36%) | catalogued as COSV100878114; called by muse, mutect2, varscan2
- C1orf87 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 54/121 reads (45%) | catalogued as rs147997086, COSV64596556; called by muse, mutect2, varscan2
- C2orf81 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV51764491; called by muse, mutect2, varscan2
- C9orf64 | c.713C>A p.A238D | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59032249; called by muse, mutect2, varscan2
- CABLES2 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as rs375112262; called by muse, mutect2, varscan2
- CACNA1D | c.3622G>A p.E1208K (on ENST00000350061 / NM_001128840.3; = p.E1228K on NM_000720.4) | Missense Mutation (SNP) | VAF 18/352 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55445291; called by muse, mutect2
- CALCOCO1 | c.1303C>T p.R435* | Nonsense Mutation (SNP) | VAF 42/145 reads (29%) | catalogued as rs1267227310, COSV50416408; called by muse, mutect2, varscan2
- CANX | c.1638G>T p.E546D | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as rs146720093; called by muse, mutect2, varscan2
- CASK | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 71/208 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1310982151, COSV59363268; called by muse, mutect2, varscan2
- CCDC168 | c.10727C>T p.S3576L | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs765838371, COSV59421777; called by muse, mutect2, varscan2
- CCDC181 | c.1247G>A p.R416Q (on ENST00000367806 / NM_001300969.1; = p.R415Q on NM_021179.2) | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs773347654, COSV61393478; called by muse, mutect2, varscan2
- CCDC185 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.025); catalogued as rs1244788991; called by muse, mutect2, varscan2
- CCDC24 | c.433G>T p.D145Y | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs758998426; called by muse, mutect2, varscan2
- CCDC39 | c.1796G>A p.R599Q | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs541958184, COSV56478424; called by muse, mutect2, varscan2
- CCDC83 | c.739T>G p.L247V | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.797); catalogued as rs762973972, COSV104381831; called by muse, mutect2, varscan2
- CCDC88A | c.1750G>T p.D584Y | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55058141; called by muse, mutect2, varscan2
- CCP110 | c.2668C>T p.R890* | Nonsense Mutation (SNP) | VAF 21/65 reads (32%) | catalogued as rs1216160727; called by muse, mutect2, varscan2
- CCT6B | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 68/211 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs577930141, COSV58488929; called by muse, mutect2, varscan2
- CD3G | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 128/364 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.804); catalogued as rs201752677, COSV99416902; ClinVar: uncertain significance; called by muse, varscan2
- CDC23 | c.932G>A p.S311N | Missense Mutation (SNP) | VAF 71/204 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV67510525; called by muse, mutect2, varscan2
- CDH10 | c.104G>T p.R35I | Missense Mutation (SNP) | VAF 46/308 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs545638636, COSV52579683, COSV52599865; called by muse, mutect2, varscan2
- CDH15 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs374936482; called by muse, varscan2
- CDH18 | c.2176G>T p.D726Y | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99932413, COSV99935122; called by muse, mutect2
- CDH18 | c.1664G>A p.R555K | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV56900038; called by muse, varscan2
- CDH23 | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs909705325, COSV54955943; called by muse, mutect2, varscan2
- CDHR3 | c.1609C>A p.L537I | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV58421787; called by muse, mutect2, varscan2
- CDK20 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs761951896; called by muse, mutect2, varscan2
- CEP135 | c.3316G>A p.E1106K | Missense Mutation (SNP) | VAF 64/127 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs145519211; called by muse, mutect2, varscan2
- CEP162 | c.3859C>A p.L1287I | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs370171466; called by muse, mutect2, varscan2
- CEP19 | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 52/125 reads (42%) | catalogued as rs1476033976, COSV56359208; called by muse, mutect2, varscan2
- CFAP52 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs757527507; called by muse, mutect2, varscan2
- CHD6 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs767786630; called by muse, mutect2, varscan2
- CHD8 | c.5680C>T p.R1894W (on ENST00000646647 / NM_001170629.2; = p.R1615W on NM_020920.4) | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs974840941; called by muse, mutect2, varscan2
- CHPT1 | c.1039G>T p.E347* | Nonsense Mutation (SNP) | VAF 48/144 reads (33%) | catalogued as COSV57148307; called by muse, mutect2, varscan2
- CLCN5 | c.1769G>T p.R590I | Missense Mutation (SNP) | VAF 56/244 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.136); catalogued as COSV56583236; called by muse, mutect2, varscan2
- CLDN17 | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 62/162 reads (38%) | catalogued as rs377679902; called by muse, mutect2, varscan2
- CLMN | c.1693A>C p.K565Q | Missense Mutation (SNP) | VAF 77/189 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.441); catalogued as COSV54179269; called by muse, mutect2, varscan2
- CNNM3 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 78/246 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); catalogued as rs370817712; called by muse, mutect2, varscan2
- CNTNAP5 | c.3710C>T p.S1237L | Missense Mutation (SNP) | VAF 68/163 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1261090777, COSV101443483; called by muse, mutect2, varscan2
- COG2 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs748137002; called by muse, mutect2, varscan2
- COL19A1 | c.2085C>A p.F695L | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.075); catalogued as COSV59568647; called by muse, mutect2, varscan2
- COL27A1 | c.3157C>T p.R1053* | Nonsense Mutation (SNP) | VAF 46/194 reads (24%) | catalogued as COSV61921243; called by muse, mutect2, varscan2
- COL5A2 | c.332G>T p.R111I | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.425); catalogued as COSV66408231, COSV66409549; called by muse, mutect2, varscan2
- COL5A3 | c.5122G>A p.E1708K | Missense Mutation (SNP) | VAF 17/202 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as rs563109290, COSV53409530; called by muse, mutect2
- COL5A3 | c.762G>T p.K254N | Missense Mutation (SNP) | VAF 25/218 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.227); catalogued as rs984062284; called by muse, mutect2, varscan2
- COL6A5 | c.4988G>A p.R1663Q | Missense Mutation (SNP) | VAF 19/212 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1335620147, COSV55194459; called by muse, mutect2
- COL7A1 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 83/212 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs777688853, COSV60393572; called by muse, mutect2, varscan2
- COPS7B | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 114/337 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as rs147144693; called by muse, mutect2, varscan2
- CORIN | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs202244872, COSV56698297; called by muse, mutect2, varscan2
- CP | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 86/257 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52829870; called by muse, mutect2, varscan2
- CPA3 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1304514609, COSV104406590, COSV56044590, COSV99936029; called by muse, mutect2, varscan2
- CPM | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.063); catalogued as rs769607646, COSV100615257; called by muse, mutect2, varscan2
- CPNE4 | c.647C>A p.S216Y | Missense Mutation (SNP) | VAF 60/185 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV70192770, COSV70201760; called by muse, mutect2, varscan2
- CREBBP | c.3821C>T p.T1274I | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs771768342; called by muse, mutect2, varscan2
- CRMP1 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as rs376766526, COSV61478985; called by muse, mutect2, varscan2
- CSRP2 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs1457151294, COSV60702935; called by muse, mutect2, varscan2
- CTNNA3 | c.2383G>T p.E795* | Nonsense Mutation (SNP) | VAF 37/108 reads (34%) | catalogued as COSV65521007; called by muse, mutect2, varscan2
- CTNNB1 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 69/244 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as COSV62707932; called by muse, mutect2, varscan2
- CUL2 | c.1302C>A p.F434L | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as rs764651797, COSV101039017, COSV66079563; called by muse, mutect2, varscan2
- CWC22 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.977); catalogued as rs752954929; called by muse, mutect2, varscan2
- CYBB | c.631C>A p.L211I | Missense Mutation (SNP) | VAF 83/216 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV101059670; called by muse, mutect2, varscan2
- CYP19A1 | c.713C>A p.S238Y | Missense Mutation (SNP) | VAF 73/196 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV99547887; called by muse, mutect2, varscan2
- CYP27C1 | c.95G>T p.R32I | Missense Mutation (SNP) | VAF 74/242 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100079991, COSV58866752; called by muse, mutect2, varscan2
- CYP8B1 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.124); catalogued as rs200599611, COSV60226987; called by muse, mutect2
- CYTH2 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.182); catalogued as rs376539291; called by muse, mutect2, varscan2
- DCBLD2 | c.1674G>T p.K558N | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1312556488; called by muse, mutect2, varscan2
- DCDC1 | c.2513C>A p.S838Y | Missense Mutation (SNP) | VAF 84/225 reads (37%) | SIFT tolerated (1); PolyPhen possibly damaging (0.906); catalogued as COSV100664174; called by muse, mutect2, varscan2
- DCDC2 | c.1371T>G p.I457M | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); catalogued as rs770029938; called by muse, mutect2, varscan2
- DCLRE1C | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 70/203 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.085); catalogued as rs772627259, COSV63182733; called by muse, mutect2, varscan2
- DDR2 | c.2141G>A p.R714Q | Missense Mutation (SNP) | VAF 110/318 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63369217; called by muse, mutect2, varscan2
- DDX18 | c.1105C>T p.R369* | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | catalogued as rs1478961203; called by muse, mutect2, varscan2
- DGAT2 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1323973590; called by muse, mutect2, varscan2
- DGKD | c.397G>T p.E133* (on ENST00000264057 / NM_152879.3; = p.E89* on NM_003648.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 48/155 reads (31%) | catalogued as rs199985859, COSV51038365; called by muse, mutect2, varscan2
- DHX30 | c.2877G>T p.E959D (on ENST00000445061 / NM_138615.3; = p.E920D on NM_014966.3) | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV53140531; called by muse, mutect2, varscan2
- DIAPH3 | c.2914G>A p.E972K (on ENST00000400324 / NM_001042517.2; = p.E709K on NM_030932.3) | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as rs781747042, COSV57367897; called by muse, mutect2, varscan2
- DIP2B | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.295); catalogued as rs148726776; called by muse, varscan2
- DISP3 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99609257; called by muse, mutect2, varscan2
- DLGAP2 | c.2908C>T p.R970W | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs755873139, COSV70097859; called by muse, mutect2, varscan2
- DMD | c.8950G>T p.E2984* | Nonsense Mutation (SNP) | VAF 153/423 reads (36%) | catalogued as COSV58893091; called by muse, mutect2, varscan2
- DNAAF1 | c.480G>T p.M160I | Missense Mutation (SNP) | VAF 180/541 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV57577350; called by muse, mutect2, varscan2
- DNAH17 | c.1451C>T p.S484L | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs144333252; called by muse, varscan2
- DNAH8 | c.10496G>A p.R3499H | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs534987499, COSV59452324; called by muse, mutect2, varscan2
- DNAH9 | c.8641C>A p.L2881I | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.764); catalogued as COSV52377991; called by muse, mutect2, varscan2
- DNAI3 | c.1511G>A p.R504Q | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as rs747622337, COSV54001312; called by muse, mutect2, varscan2
- DNAJC9 | c.777G>T p.K259N | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99654721; called by muse, mutect2, varscan2
- DNHD1 | c.3443G>A p.R1148Q | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as rs1033715871, COSV54433417; called by muse, mutect2, varscan2
- DOCK3 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866059893, COSV56544267; called by muse, mutect2, varscan2
- DOCK8 | c.5397C>A p.F1799L | Missense Mutation (SNP) | VAF 122/334 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV101210075; called by muse, mutect2, varscan2
- DRC7 | c.2107C>T p.R703* | Nonsense Mutation (SNP) | VAF 90/225 reads (40%) | catalogued as rs751162679, COSV61053469; called by muse, mutect2, varscan2
- DRD3 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 24/233 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0.015); catalogued as rs200082316, COSV55679440; called by muse, mutect2, varscan2
- DSEL | c.2779C>T p.R927C | Missense Mutation (SNP) | VAF 84/274 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs773237343, COSV59490960; called by muse, mutect2, varscan2
- DSG2 | c.3151C>A p.L1051I | Missense Mutation (SNP) | VAF 126/434 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.102); catalogued as COSV99852816; called by muse, mutect2, varscan2
- DST | c.2425G>A p.E809K (on ENST00000361203 / NM_001374722.1; = p.E483K on NM_001723.6) | Missense Mutation (SNP) | VAF 103/325 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs142588059; called by muse, mutect2, varscan2
- DTNA | c.2026C>T p.R676* | Nonsense Mutation (SNP) | VAF 25/253 reads (10%) | catalogued as COSV52017783; called by muse, mutect2
- DUSP16 | c.1514G>A p.R505Q | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as rs1258427627, COSV53806510; called by muse, mutect2, varscan2
- DYNC2H1 | c.2008G>T p.E670* | Nonsense Mutation (SNP) | VAF 52/171 reads (30%) | catalogued as COSV62088003; called by muse, mutect2, varscan2
- ECHDC1 | c.522G>T p.M174I (on ENST00000531967 / NM_001139510.1; = p.M168I on NM_001002030.2) | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.194); catalogued as COSV58933389; called by muse, varscan2
- EFCAB5 | c.2722G>T p.E908* | Nonsense Mutation (SNP) | VAF 21/66 reads (32%) | catalogued as rs1194630533, COSV57928684; called by muse, varscan2
- EFCAB6 | c.1603G>A p.V535I | Missense Mutation (SNP) | VAF 16/185 reads (9%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs770841643, COSV99412557; called by muse, mutect2
- EFR3A | c.931C>T p.R311* | Nonsense Mutation (SNP) | VAF 42/174 reads (24%) | catalogued as COSV54455473; called by muse, mutect2, varscan2
- EGF | c.3025G>A p.G1009R | Missense Mutation (SNP) | VAF 121/352 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775725663; called by muse, mutect2, varscan2
- EHBP1L1 | c.3233G>A p.R1078Q | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs761416305; called by muse, mutect2, varscan2
- EIF2A | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 66/189 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs749842765; called by muse, mutect2, varscan2
- ELAVL4 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as rs1175579240, COSV63915417; called by muse, mutect2, varscan2
- ENKUR | c.659C>A p.S220Y | Missense Mutation (SNP) | VAF 62/313 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs575120495, COSV58632877; called by muse, mutect2, varscan2
- EPHX4 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749290050, COSV64889068; called by muse, varscan2
- EXOC1 | c.2225G>A p.R742Q | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs373611067, COSV100637863; called by muse, mutect2, varscan2
- EYS | c.8921C>A p.S2974* (on ENST00000370621 / NM_001292009.1; = p.S2953* on NM_001142800.2) | Nonsense Mutation (SNP) | VAF 103/329 reads (31%) | catalogued as CM157903; called by muse, mutect2, varscan2
- F5 | c.1299C>T p.I433= | Splice Region (SNP) | VAF 70/250 reads (28%) | catalogued as rs541673477, COSV63121250; called by muse, mutect2, varscan2
- FAM131B | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 67/205 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs1336634388; called by muse, mutect2, varscan2
- FAM160A1 | c.911G>T p.R304L | Missense Mutation (SNP) | VAF 103/300 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs112244723, COSV101475051; called by muse, mutect2, varscan2
- FAM160A2 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs201084258; called by muse, mutect2, varscan2
- FARS2 | c.1143C>A p.F381L | Missense Mutation (SNP) | VAF 68/226 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV51166002, COSV51169053; called by muse, mutect2, varscan2
- FAT3 | c.1699C>T p.R567* | Nonsense Mutation (SNP) | VAF 49/147 reads (33%) | catalogued as rs1230731830, COSV53074844; called by muse, mutect2, varscan2
- FBXL20 | c.113C>A p.S38Y | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99234276; called by muse, mutect2, varscan2
- FBXW10 | c.2406G>T p.K802N | Missense Mutation (SNP) | VAF 30/411 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as rs766712663, COSV57059522; called by muse, mutect2
- FCER1A | c.168C>A p.F56L | Missense Mutation (SNP) | VAF 79/232 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV63666623, COSV63667526; called by muse, mutect2, varscan2
- FCRLA | c.1075G>A p.G359S (on ENST00000367959; = p.G336S on NM_032738.4) | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as rs199501005, COSV99376165; called by muse, mutect2, varscan2
- FLNA | c.3095G>A p.R1032H | Missense Mutation (SNP) | VAF 113/326 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.631); catalogued as rs781782783, COSV61043623; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLT4 | c.2525G>A p.R842Q | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs770500099, COSV56112992; called by muse, mutect2, varscan2
- FRMPD1 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs559939562, COSV63383767, COSV63384072; called by muse, mutect2, varscan2
- FRMPD2 | c.2560G>T p.E854* | Nonsense Mutation (SNP) | VAF 46/135 reads (34%) | catalogued as COSV100564016, COSV59720132; called by muse, mutect2, varscan2
- FRY | c.8920G>A p.E2974K | Missense Mutation (SNP) | VAF 98/314 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs747302144, COSV66510854; called by muse, mutect2, varscan2
- FSIP2 | c.2061G>T p.K687N | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as rs1559024977; called by muse, mutect2, varscan2
- GALNT3 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 115/257 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as rs767939917, COSV67061845; called by muse, mutect2, varscan2
- GCC2 | c.1772C>A p.S591Y | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs920522699, COSV100565136; called by muse, mutect2, varscan2
- GCNT3 | c.89C>A p.S30Y | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.246); catalogued as COSV68532394; called by muse, mutect2
- GFPT2 | c.1093C>T p.R365* | Nonsense Mutation (SNP) | VAF 60/177 reads (34%) | catalogued as rs376764676; called by muse, mutect2, varscan2
- GLI2 | c.1470C>T p.F490= (on ENST00000361492 / NM_001374353.1; = p.F507= on NM_005270.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 17/53 reads (32%) | catalogued as rs544791528, COSV58035231; called by muse, mutect2, varscan2
- GLS2 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 77/242 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.313); catalogued as rs150644220; called by muse, mutect2, varscan2
- GNPAT | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 149/442 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV104427122, COSV64153987; called by muse, mutect2, varscan2
- GPR84 | c.955C>T p.R319* | Nonsense Mutation (SNP) | VAF 39/122 reads (32%) | catalogued as rs574443740, COSV104386089; called by muse, mutect2, varscan2
- GRAMD2A | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 49/161 reads (30%) | catalogued as COSV59032797, COSV59033703; called by muse, mutect2, varscan2
- GRM3 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs1227263804, COSV64469309; called by muse, mutect2, varscan2
- GTDC1 | c.887A>C p.K296T | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs769429655; called by muse, mutect2, varscan2
- HABP2 | c.149A>C p.N50T | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV63636606; called by muse, mutect2
- HAL | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 57/319 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376855010; called by muse, mutect2, varscan2
- HDAC6 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 77/201 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV61930334; called by muse, mutect2, varscan2
- HDLBP | c.3685C>T p.R1229W | Missense Mutation (SNP) | VAF 89/227 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771691256, COSV51477742; called by muse, mutect2, varscan2
- HECA | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761042563; called by muse, mutect2, varscan2
- HECW1 | c.4339C>T p.R1447W | Missense Mutation (SNP) | VAF 71/212 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765023043, COSV101223445, COSV101223887; called by muse, mutect2, varscan2
- HMCN1 | c.666C>A p.H222Q | Missense Mutation (SNP) | VAF 66/207 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54919404; called by muse, mutect2, varscan2
- HMCN1 | c.6917G>A p.R2306Q | Missense Mutation (SNP) | VAF 95/262 reads (36%) | SIFT tolerated (1); PolyPhen possibly damaging (0.653); catalogued as rs137853916, COSV54894302; ClinVar: not provided; called by muse, mutect2, varscan2
- HNRNPH2 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 44/114 reads (39%) | catalogued as COSV54508573; called by muse, mutect2, varscan2
- HOXA13 | c.47T>C p.V16A | Missense Mutation (SNP) | VAF 43/399 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs778036975; called by muse, mutect2, varscan2
- HSP90AA1 | c.199C>A p.L67I | Missense Mutation (SNP) | VAF 157/447 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV58230579; called by muse, mutect2, varscan2
- HSP90AB1 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 46/409 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.303); catalogued as rs371199616; called by muse, mutect2, varscan2
- HSP90B1 | c.2404G>T p.E802* | Nonsense Mutation (SNP) | VAF 20/70 reads (29%) | catalogued as rs1340884541; called by muse, mutect2, varscan2
- HTR2B | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 131/369 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.078); catalogued as rs781269061, COSV51449246; called by muse, mutect2, varscan2
- IL12RB1 | c.124+4C>T | Splice Region (SNP) | VAF 156/458 reads (34%) | catalogued as rs771664229; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1027C>T p.R343* | Nonsense Mutation (SNP) | VAF 130/415 reads (31%) | catalogued as rs1475549924, COSV56258619; called by muse, mutect2, varscan2
- IL7 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as COSV55672903, COSV55674084, COSV99805072; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 65/170 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1204125033, COSV99860871; called by muse, mutect2, varscan2
- ITGA2 | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 197/567 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs113282066, COSV56856415; called by muse, mutect2, varscan2
- ITGA6 | c.1831A>G p.N611D (on ENST00000442250; = p.N572D on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/365 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.46); catalogued as rs1389261715; called by muse, mutect2
- JRKL | c.498G>T p.E166D | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.551); catalogued as COSV99567120; called by muse, mutect2, varscan2
- KCNC2 | c.1141G>T p.E381* | Nonsense Mutation (SNP) | VAF 76/263 reads (29%) | catalogued as rs750183803, COSV100128562; called by muse, mutect2, varscan2
- KCND3 | c.1648C>T p.R550C | Missense Mutation (SNP) | VAF 211/597 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as rs778141653, COSV56192026; called by muse, mutect2, varscan2
- KCNE2 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 78/193 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs368865412, COSV51709534; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNH1 | c.1696G>A p.D566N (on ENST00000271751 / NM_172362.3; = p.D539N on NM_002238.4) | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs768835601, COSV55083991, COSV55100740; called by muse, mutect2, varscan2
- KDM5A | c.2156G>A p.R719H | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as rs1237979376; called by muse, mutect2, varscan2
- KDM5B | c.4015C>T p.L1339F | Missense Mutation (SNP) | VAF 67/183 reads (37%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.961); catalogued as rs750748976; called by muse, mutect2, varscan2
- KDM6A | c.2911C>T p.R971C | Missense Mutation (SNP) | VAF 75/211 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65040820; called by muse, mutect2, varscan2
- KIF13A | c.4138C>T p.R1380W | Missense Mutation (SNP) | VAF 76/250 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs372857233, COSV52458147; called by muse, varscan2
- KIF15 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201923210; called by muse, mutect2, varscan2
- KIF27 | c.4084G>T p.E1362* | Nonsense Mutation (SNP) | VAF 72/261 reads (28%) | catalogued as COSV52827514; called by muse, mutect2, varscan2
- KIF4B | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 110/291 reads (38%) | catalogued as COSV70527742, COSV70528379; called by muse, mutect2, varscan2
- LHCGR | c.1906C>A p.L636I | Missense Mutation (SNP) | VAF 25/337 reads (7%) | SIFT tolerated (1); PolyPhen probably damaging (0.984); catalogued as COSV54299317, COSV54299540; called by muse, mutect2
- LIG1 | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 32/298 reads (11%) | catalogued as COSV99619318; called by muse, mutect2, varscan2
- LIPF | c.204G>T p.K68N | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV53286330; called by muse, mutect2, varscan2
- LIPH | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 89/270 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs371388993; called by muse, mutect2, varscan2
- LMTK2 | c.2230G>T p.D744Y | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.24); catalogued as rs532052708; called by muse, mutect2, varscan2
- LNP1 | c.257G>A p.R86K | Missense Mutation (SNP) | VAF 38/246 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV67346895; called by muse, varscan2
- LNPEP | c.932T>G p.F311C | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51481527; called by muse, mutect2, varscan2
- LNPK | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 9/150 reads (6%) | catalogued as COSV55826518; called by muse, mutect2
- LRP1B | c.1837C>A p.L613I | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs755741370; called by muse, varscan2
- LRP2BP | c.1037G>T p.R346I | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as rs1298314778, COSV53013113; called by muse, mutect2, varscan2
- LRRC49 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs369249823; called by muse, mutect2, varscan2
- LRRC63 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.197); catalogued as rs556213982; called by muse, mutect2, varscan2
- LTA4H | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs747801691; called by muse, mutect2, varscan2
- MAGEE1 | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as COSV63909477; called by muse, mutect2, varscan2
- MAN1A1 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 52/123 reads (42%) | catalogued as COSV63781353; called by muse, mutect2, varscan2
- MAT2B | c.949G>T p.E317* | Nonsense Mutation (SNP) | VAF 18/161 reads (11%) | catalogued as COSV55200260; called by muse, mutect2, varscan2
- MBOAT2 | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.786); catalogued as COSV60010721; called by muse, mutect2, varscan2
- MCM9 | c.2321C>T p.S774L | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs754615634, COSV100309836; called by muse, mutect2, varscan2
- MEGF6 | c.3943G>A p.A1315T | Missense Mutation (SNP) | VAF 93/228 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.062); catalogued as rs759651996, COSV53889618; called by muse, mutect2, varscan2
- MGA | c.1879C>T p.R627* | Nonsense Mutation (SNP) | VAF 46/89 reads (52%) | catalogued as COSV54950190; called by muse, mutect2, varscan2
- MGAM2 | c.2451G>T p.K817N | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.048); catalogued as rs1374641615; called by muse, mutect2, varscan2
- MMADHC | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1344191765, COSV57573543; called by muse, mutect2, varscan2
- MMP3 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55405195; called by muse, mutect2, varscan2
- MOSPD2 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.434); catalogued as rs1439661540, COSV66859647; called by muse, mutect2, varscan2
- MOXD1 | c.1207C>T p.R403* | Nonsense Mutation (SNP) | VAF 51/156 reads (33%) | catalogued as rs781416813; called by muse, mutect2, varscan2
- MPP7 | c.1357C>T p.R453W | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs35450618; called by muse, mutect2, varscan2
- MTSS1 | c.1657G>A p.D553N | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.061); catalogued as rs757540011, COSV52674884; called by muse, mutect2, varscan2
- MUC17 | c.8297C>T p.S2766F | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV60283834, COSV60305361; called by muse, mutect2, varscan2
- MUC5B | c.8458G>A p.E2820K | Missense Mutation (SNP) | VAF 202/662 reads (31%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs369723768; called by muse, mutect2, varscan2
- MYBPC1 | c.1073G>A p.R358K (on ENST00000550270 / NM_206820.2; = p.R383K on NM_002465.4) | Missense Mutation (SNP) | VAF 77/234 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as COSV62254357; called by muse, mutect2, varscan2
- MYCT1 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs748344102, COSV100924088, COSV65890890; called by muse, mutect2, varscan2
- MYH2 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 170/453 reads (38%) | catalogued as COSV55440934, COSV55441376; called by muse, varscan2
- MYO3A | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752594701, COSV56327010; called by muse, mutect2, varscan2
- MYO3A | c.4388C>T p.S1463L | Missense Mutation (SNP) | VAF 110/314 reads (35%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.012); catalogued as rs1016218355, COSV56321514; called by muse, mutect2, varscan2
- MYO6 | c.1831G>T p.E611* | Nonsense Mutation (SNP) | VAF 27/118 reads (23%) | catalogued as rs1362017839; called by muse, mutect2, varscan2
- MYOCD | c.2315G>A p.R772Q | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs771058548, COSV58497700; called by muse, mutect2, varscan2
- MYOM2 | c.3775G>T p.E1259* | Nonsense Mutation (SNP) | VAF 15/151 reads (10%) | catalogued as COSV50701963; called by muse, mutect2, varscan2
- N4BP2 | c.3938G>T p.R1313I | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs1326397279, COSV54702894, COSV99789270; called by muse, mutect2, varscan2
- NAV3 | c.3284A>C p.K1095T | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1356376419; called by muse, mutect2, varscan2
- NAV3 | c.5327G>A p.R1776Q | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs781748835, COSV99889380; called by muse, mutect2, varscan2
- NBEA | c.5128G>A p.E1710K | Missense Mutation (SNP) | VAF 49/233 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); catalogued as rs561239166, COSV59766532; called by muse, mutect2, varscan2
- NDFIP1 | c.652C>A p.L218I | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV54076513; called by muse, mutect2, varscan2
- NEB | c.1285G>T p.D429Y | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.786); catalogued as rs577939684; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEDD4L | c.1494C>A p.F498L (on ENST00000400345 / NM_001144967.3; = p.F478L on NM_015277.6) | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV99896174; called by muse, mutect2, varscan2
- NIBAN3 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV56309818; called by muse, mutect2, varscan2
- NKTR | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as rs536150678, COSV51769497; called by muse, mutect2, varscan2
- NLN | c.1729C>T p.R577C | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1274961449; called by muse, mutect2, varscan2
- NLRP1 | c.3771C>A p.C1257* | Nonsense Mutation (SNP) | VAF 27/73 reads (37%) | catalogued as COSV52563062; called by muse, mutect2, varscan2
- NNMT | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 84/220 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as rs750805211, COSV55473279, COSV55473688; called by muse, mutect2, varscan2
- NOL4L | c.480C>T p.I160= | Splice Region (SNP) | VAF 34/85 reads (40%) | catalogued as rs990148126, COSV52408302; called by muse, mutect2, varscan2
- NOX1 | c.128G>T p.R43I | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV54193332, COSV54195564, COSV99471576; called by muse, varscan2
- NRG3 | c.2059G>A p.E687K (on ENST00000404547 / NM_001370084.1; = p.E663K on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 93/286 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs757060096, COSV99058677; called by muse, mutect2, varscan2
- NUP107 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs771657090; called by muse, mutect2, varscan2
- NVL | c.2260C>T p.R754C | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778885446, COSV55872588; called by muse, mutect2, varscan2
- OBI1 | c.1729C>A p.L577I | Missense Mutation (SNP) | VAF 77/231 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99932665; called by muse, mutect2, varscan2
- OR10J1 | c.22C>T p.L8F | Missense Mutation (SNP) | VAF 62/141 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs748859442; called by muse, mutect2, varscan2
- OR13D1 | c.132C>A p.F44L | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs759739126, COSV59513579, COSV59513660; called by muse, mutect2, varscan2
- OR2T3 | c.942G>T p.M314I | Missense Mutation (SNP) | VAF 92/442 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs552029313, COSV100613474, COSV62081866; called by muse, varscan2
- OR2T34 | c.942G>T p.M314I | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1262825272; called by muse, varscan2
- OR4C46 | c.312C>A p.F104L | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.011); catalogued as rs186299776; called by muse, mutect2, varscan2
- OR4L1 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.913); catalogued as rs748572769; called by muse, mutect2, varscan2
- OR52B4 | c.670C>A p.L224I | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101281603; called by muse, mutect2, varscan2
- OR5D16 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs781123999, COSV65721835, COSV65723133; called by muse, mutect2, varscan2
- OR5K1 | c.212C>A p.S71Y | Missense Mutation (SNP) | VAF 62/193 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV60303861, COSV60304090; called by muse, mutect2, varscan2
- OR8H1 | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 23/56 reads (41%) | catalogued as rs761763741, COSV57295920; called by muse, mutect2, varscan2
- P3H3 | c.2197C>T p.R733W | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1048589361; called by muse, mutect2, varscan2
- PABPC3 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV55796483; called by muse, mutect2, varscan2
- PARM1 | c.237G>T p.K79N | Missense Mutation (SNP) | VAF 39/319 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV56651524; called by muse, mutect2, varscan2
- PAX6 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 93/285 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV53794089; called by muse, mutect2, varscan2
- PAX7 | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 100/264 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1185057613, COSV69314649; called by muse, mutect2, varscan2
- PBX3 | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100655602; called by muse, mutect2, varscan2
- PCDHA8 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 42/245 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.132); catalogued as rs536759978, COSV65336847; called by muse, mutect2, varscan2
- PCDHB15 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 63/191 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782718695, COSV51147261; called by muse, mutect2, varscan2
- PCDHGA2 | c.2197A>G p.T733A | Missense Mutation (SNP) | VAF 172/477 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53979039; called by muse, mutect2, varscan2
- PCF11 | c.4537G>A p.E1513K | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1406924040, COSV53529792; called by muse, mutect2, varscan2
- PCSK1 | c.264G>T p.K88N | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.139); catalogued as COSV60735068; called by muse, mutect2, varscan2
- PCSK2 | c.1499T>G p.F500C | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV52726246; called by muse, mutect2, varscan2
- PDE11A | c.2575C>T p.R859W | Missense Mutation (SNP) | VAF 68/225 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773631747; called by muse, varscan2
- PDGFRA | c.787G>T p.E263* | Nonsense Mutation (SNP) | VAF 38/322 reads (12%) | catalogued as COSV57275774; called by muse, mutect2, varscan2
- PDILT | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs778919842, COSV56706493; called by muse, mutect2, varscan2
- PDZD2 | c.4922C>T p.S1641L | Missense Mutation (SNP) | VAF 79/195 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs781462971, COSV56869443; called by muse, mutect2, varscan2
- PDZK1 | c.1501G>T p.E501* | Nonsense Mutation (SNP) | VAF 24/320 reads (8%) | catalogued as COSV100572453; called by muse, mutect2
- PGBD1 | c.1951C>T p.R651C | Missense Mutation (SNP) | VAF 94/268 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.18); catalogued as rs768438454, COSV99459892, COSV99460428; called by muse, mutect2, varscan2
- PGM5 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV67163238; called by muse, mutect2, varscan2
- PHKA1 | c.1435C>A p.L479I | Missense Mutation (SNP) | VAF 28/445 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59808347; called by muse, mutect2
- PIGC | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV51130629; called by muse, varscan2
- PIGN | c.2329C>T p.R777* | Nonsense Mutation (SNP) | VAF 75/201 reads (37%) | catalogued as rs927198220, COSV62947877; called by muse, mutect2, varscan2
- PIK3CG | c.2428C>A p.P810T | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759433704, COSV63246943, COSV63248197, COSV63255136; called by muse, mutect2, varscan2
- PIK3R1 | c.1740C>A p.Y580* (on ENST00000521381 / NM_181523.3; = p.Y310* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 10/114 reads (9%) | catalogued as COSV99141168; called by muse, mutect2
- PITPNM1 | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763245484, COSV56874631; called by muse, mutect2
- PJA2 | c.328A>C p.N110H | Missense Mutation (SNP) | VAF 72/229 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as rs1432411580; called by muse, mutect2, varscan2
- PKD1L1 | c.4738C>T p.R1580W | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs762682035, COSV56977414; called by muse, mutect2, varscan2
- PKD1L3 | c.4276G>A p.E1426K | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375182382, COSV58664799; called by muse, mutect2, varscan2
- PLA1A | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 87/210 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.057); catalogued as rs200921577, COSV56330613; called by muse, mutect2, varscan2
- PLCH1 | c.3020G>T p.R1007I (on ENST00000340059 / NM_001130960.2; = p.R999I on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.075); catalogued as COSV58211760; called by muse, mutect2, varscan2
- PLCZ1 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.205); catalogued as rs779427460, COSV56848630; called by muse, mutect2, varscan2
- PLEKHA4 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.451); catalogued as rs200342983; called by muse, mutect2, varscan2
- PLEKHA6 | c.1772C>A p.S591* | Nonsense Mutation (SNP) | VAF 60/173 reads (35%) | catalogued as COSV55341529; called by muse, mutect2, varscan2
- POLI | c.1540G>T p.D514Y | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV54188800; called by muse, mutect2, varscan2
- POLR3A | c.2700C>A p.F900L | Missense Mutation (SNP) | VAF 124/371 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.093); catalogued as COSV100965600; called by muse, mutect2, varscan2
- POTEC | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 16/245 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV100743985; called by muse, mutect2
- POU6F2 | c.1822C>T p.R608C | Missense Mutation (SNP) | VAF 188/491 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV68877952; called by muse, mutect2, varscan2
- PPFIA2 | c.949G>T p.E317* | Nonsense Mutation (SNP) | VAF 63/174 reads (36%) | catalogued as COSV61021386; called by muse, mutect2, varscan2
- PPIG | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 80/235 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs775195515, COSV53644097; called by muse, mutect2, varscan2
- PRDM1 | c.2174G>A p.R725Q | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as rs940196192, COSV64846986; called by muse, mutect2, varscan2
- PREX2 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as rs200600940; called by muse, mutect2, varscan2
- PRKDC | c.4918G>A p.E1640K | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as rs780182143; called by muse, mutect2, varscan2
- PSG4 | c.944G>T p.R315L | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.44); catalogued as COSV54938968, COSV99737771; called by muse, mutect2
- PTCHD4 | c.2294C>A p.S765Y | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV100261961; called by muse, mutect2, varscan2
- PTEN | c.167T>G p.F56C | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748031178; called by muse, mutect2, varscan2
- PTEN | c.1021T>G p.F341V | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1554825652, COSV64288696, COSV64295085; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTEN | c.1022T>G p.F341C | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64294074, COSV64295090; called by muse, mutect2, varscan2
- PTGIR | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.109); catalogued as rs1168675238; called by muse, mutect2, varscan2
- PTPRD | c.2549T>C p.F850S | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as COSV61935898; called by muse, mutect2, varscan2
- PTPRG | c.2974C>T p.R992C | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772358512, COSV55635053; called by muse, mutect2, varscan2
- PYGM | c.1790A>C p.K597T | Missense Mutation (SNP) | VAF 66/424 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.185); catalogued as COSV51215380; called by muse, mutect2, varscan2
- QSER1 | c.2534G>T p.R845I (on ENST00000399302; = p.R974I on NM_001076786.3) | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67900032; called by muse, mutect2, varscan2
- R3HDM1 | c.3079C>T p.R1027C | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.549); catalogued as rs754736584, COSV51524492, COSV99926167; called by muse, mutect2, varscan2
- RAB17 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs1307393059; called by muse, mutect2, varscan2
- RAB3GAP2 | c.2139C>A p.F713L | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV62782730; called by muse, mutect2, varscan2
- RABEP1 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 104/286 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs764134334, COSV52582813; called by muse, mutect2, varscan2
- RANBP2 | c.6182A>C p.K2061T | Missense Mutation (SNP) | VAF 233/665 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51699661; called by muse, mutect2, varscan2
- RAP1GDS1 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0.027); catalogued as rs773266313, COSV52787457; called by muse, mutect2, varscan2
- RAPGEF1 | c.3126C>A p.F1042L | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as rs771831646, COSV64697474; called by muse, mutect2, varscan2
- RASAL2 | c.654C>A p.F218L | Missense Mutation (SNP) | VAF 8/179 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV62718620; called by muse, mutect2
- RASGRF2 | c.2175C>A p.F725L | Missense Mutation (SNP) | VAF 101/286 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.469); catalogued as rs140660937; called by muse, mutect2, varscan2
- RB1 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1237070816, CM030508, COSV57296400, COSV57301331; called by muse, mutect2, varscan2
- RBM3 | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as rs781917689; called by muse, mutect2, varscan2
- REEP3 | c.661C>T p.R221* | Nonsense Mutation (SNP) | VAF 41/148 reads (28%) | catalogued as COSV100005330; called by muse, mutect2, varscan2
- REG1A | c.350C>A p.S117Y | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52070293; called by muse, mutect2, varscan2
- REV3L | c.3224C>A p.S1075Y | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV62614464; called by muse, mutect2, varscan2
- RFC1 | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.123); catalogued as rs896111059, COSV62899280; called by muse, mutect2, varscan2
- RGPD8 | c.2831C>T p.T944I | Missense Mutation (SNP) | VAF 28/902 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV100222061; called by muse, mutect2
- RGS22 | c.1089G>T p.K363N | Missense Mutation (SNP) | VAF 65/158 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV62658662; called by muse, mutect2, varscan2
- RIIAD1 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 16/256 reads (6%) | catalogued as COSV58401064; called by muse, mutect2
- RIOK2 | c.816C>A p.F272L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.861); catalogued as rs1303215288, COSV51612446; called by muse, mutect2, varscan2
- RNF19A | c.188G>T p.R63I | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV61994686; called by muse, mutect2, varscan2
- RNF40 | c.1525C>T p.R509* | Nonsense Mutation (SNP) | VAF 68/213 reads (32%) | catalogued as COSV61216042; called by muse, mutect2, varscan2
- ROBO1 | c.4870C>T p.R1624* | Nonsense Mutation (SNP) | VAF 45/125 reads (36%) | catalogued as rs755375406, COSV71392075; called by muse, mutect2, varscan2
- RP1 | c.4486G>T p.E1496* | Nonsense Mutation (SNP) | VAF 74/214 reads (35%) | catalogued as COSV104377683, COSV55127307; called by muse, mutect2, varscan2
- RPP40 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 55/147 reads (37%) | catalogued as rs771055748; called by muse, mutect2, varscan2
- RPS27A | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 33/303 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1358069546; called by muse, mutect2, varscan2
- RSPH4A | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as rs148954304; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RTN2 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 115/313 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.616); catalogued as COSV55596446; called by muse, mutect2, varscan2
- RXFP2 | c.836C>A p.S279* | Nonsense Mutation (SNP) | VAF 51/210 reads (24%) | catalogued as COSV100034008; called by muse, mutect2, varscan2
- RXFP2 | c.2164T>G p.L722V | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100034385; called by muse, mutect2, varscan2
- RYR3 | c.5563T>C p.S1855P | Missense Mutation (SNP) | VAF 34/284 reads (12%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.997); catalogued as COSV101213942; called by muse, mutect2, varscan2
- SAGE1 | c.1957C>A p.R653S | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT tolerated (0.91); PolyPhen benign (0.293); catalogued as COSV61018465; called by muse, varscan2
- SAMD11 | c.1340C>T p.S447F | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs1041991580; called by muse, mutect2, varscan2
- SAP30 | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as rs1397128317; called by muse, mutect2, varscan2
- SARDH | c.1705G>A p.A569T | Missense Mutation (SNP) | VAF 95/237 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs766700582; called by muse, mutect2, varscan2
- SCAI | c.927G>T p.M309I (on ENST00000336505 / NM_001144877.3; = p.M332I on NM_173690.5) | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs750443849; called by muse, mutect2, varscan2
- SCML2 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52622237; called by muse, mutect2, varscan2
- SCN11A | c.3990G>T p.K1330N | Missense Mutation (SNP) | VAF 54/191 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV100182390; called by muse, mutect2, varscan2
- SCN8A | c.5878C>T p.R1960W | Missense Mutation (SNP) | VAF 146/463 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); catalogued as rs1021136260; called by muse, mutect2, varscan2
- SCN9A | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.177); catalogued as rs887570747; called by muse, mutect2, varscan2
- SCUBE2 | c.2887C>T p.R963* (on ENST00000649792 / NM_001367977.2; = p.R906* on NM_020974.3) | Nonsense Mutation (SNP) | VAF 35/138 reads (25%) | catalogued as rs370986866, COSV58543084; called by muse, mutect2, varscan2
- SDHA | c.1657G>A p.D553N | Missense Mutation (SNP) | VAF 105/333 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs769882609; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SECISBP2L | c.1241C>A p.S414Y (on ENST00000559471 / NM_001193489.2; = p.S369Y on NM_014701.4) | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs751918625, COSV55932590; called by muse, mutect2, varscan2
- SEMA3E | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 157/454 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.096); catalogued as rs376950350, COSV100319033; called by muse, mutect2, varscan2
- SERPINB7 | c.849G>T p.K283N | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.258); catalogued as rs1330631134, COSV100320427, COSV60532701; called by muse, mutect2, varscan2
- SERPINI1 | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 30/174 reads (17%) | catalogued as COSV55511041; called by muse, varscan2
- SGCZ | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as rs779572116, COSV66019663; called by muse, mutect2, varscan2
- SGO2 | c.1484G>T p.R495I | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV63414585; called by muse, mutect2, varscan2
- SH3BGRL | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1262164477, COSV100943339; called by muse, mutect2, varscan2
- SIGLEC10 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV59486202; called by muse, mutect2, varscan2
- SIGLEC5 | c.1422G>T p.E474D | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV55778891; called by muse, mutect2, varscan2
- SIK3 | c.866G>A p.R289H (on ENST00000445177 / NM_001366686.2; = p.R295H on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/229 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1341117931; called by muse, mutect2
- SKIDA1 | c.1289G>A p.G430D | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as rs1564333839; called by muse, mutect2, varscan2
- SLC12A1 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 82/282 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs577894346, COSV100372285, COSV104397918; called by muse, mutect2, varscan2
- SLC22A10 | c.1557G>T p.K519N | Missense Mutation (SNP) | VAF 120/291 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1372803550; called by muse, mutect2, varscan2
- SLC22A13 | c.1587G>T p.E529D | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV61290250; called by muse, mutect2, varscan2
- SLC22A2 | c.1140C>A p.F380L | Missense Mutation (SNP) | VAF 75/228 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65265718, COSV65266317; called by muse, varscan2
- SLC25A53 | c.581C>A p.S194Y | Missense Mutation (SNP) | VAF 63/182 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62459922, COSV62460201; called by muse, mutect2, varscan2
- SLC32A1 | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 43/464 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.021); catalogued as rs1023170011, COSV54148411; called by muse, mutect2
- SLC36A4 | c.56-1G>T p.X19_splice | Splice Site (SNP) | VAF 23/50 reads (46%) | catalogued as COSV58397098; called by muse, mutect2, varscan2
- SLC3A1 | c.1322C>T p.P441L | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs779168140, CM050090, COSV99577532; called by muse, mutect2, varscan2
- SLC40A1 | c.1401C>T p.I467= | Splice Region (SNP) | VAF 28/94 reads (30%) | catalogued as rs773589070, COSV53722183, COSV53723640; called by muse, mutect2, varscan2
- SLC6A6 | c.1421T>G p.F474C | Missense Mutation (SNP) | VAF 76/229 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.22); catalogued as COSV62652991; called by muse, mutect2, varscan2
- SLC9C1 | c.3400G>T p.E1134* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as COSV59886127; called by muse, varscan2
- SLITRK3 | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1181746974, COSV53845770, COSV53848032, COSV53848768; called by muse, mutect2, varscan2
- SLITRK3 | c.893C>T p.S298L | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1359899576, COSV53845509; called by muse, mutect2, varscan2
- SLITRK3 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 43/111 reads (39%) | catalogued as COSV53851119, COSV53853602; called by muse, mutect2, varscan2
- SLITRK6 | c.1693C>A p.L565I | Missense Mutation (SNP) | VAF 35/210 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs373437250; called by muse, mutect2, varscan2
- SMC1A | c.2683C>T p.R895C | Missense Mutation (SNP) | VAF 45/361 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100447674; called by muse, mutect2, varscan2
- SMC4 | c.1145T>G p.F382C | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.855); catalogued as rs774131818, COSV100643980; called by muse, varscan2
- SMO | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.981); catalogued as rs61740964; called by muse, mutect2, varscan2
- SMPD2 | c.232A>C p.I78L | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as COSV99237975; called by muse, mutect2, varscan2
- SOCS2 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 68/214 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1409974225, COSV61391940, COSV61392211; called by muse, mutect2, varscan2
- SPAM1 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 44/136 reads (32%) | catalogued as COSV56145532; called by muse, mutect2, varscan2
- SPARCL1 | c.1890C>A p.F630L | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56806020; called by muse, mutect2, varscan2
- SPATA5 | c.1612C>T p.R538* | Nonsense Mutation (SNP) | VAF 22/215 reads (10%) | catalogued as COSV56775619; called by muse, mutect2, varscan2
- SPATA5L1 | c.1348C>T p.R450* | Nonsense Mutation (SNP) | VAF 52/152 reads (34%) | catalogued as rs769639347, COSV59745720; called by muse, mutect2, varscan2
- SPIRE1 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1453744342, COSV100563549; called by muse, mutect2, varscan2
- SPTBN2 | c.3499C>T p.R1167C | Missense Mutation (SNP) | VAF 97/270 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs1340763076, COSV59451869; called by muse, mutect2, varscan2
- SPZ1 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 23/259 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.166); catalogued as rs199787885, COSV57062860; called by muse, mutect2
- SRGAP1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs141758307; called by muse, mutect2, varscan2
- ST8SIA1 | c.763T>G p.F255V | Missense Mutation (SNP) | VAF 87/263 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV53952491; called by muse, mutect2, varscan2
- STAMBP | c.372A>C p.E124D | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs999677915; called by muse, mutect2, varscan2
- STAP1 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766139382, COSV55328960; called by muse, mutect2, varscan2
- STAT6 | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 44/129 reads (34%) | catalogued as rs1208473672; called by muse, mutect2, varscan2
- STIM2 | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 65/206 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.978); catalogued as rs763776616, COSV52836863; called by muse, mutect2, varscan2
- STXBP5L | c.2338C>T p.R780C | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs866206814, COSV56511990, COSV99874789; called by muse, mutect2, varscan2
- SULT1C2 | c.568C>A p.L190I | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs754892369, COSV104380314; called by muse, mutect2, varscan2
- SULT1E1 | c.299C>A p.S100Y | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56948706; called by muse, mutect2, varscan2
- SUPT3H | c.135-4G>A | Splice Region (SNP) | VAF 27/85 reads (32%) | catalogued as rs1448423586; called by muse, mutect2, varscan2
- SYNE2 | c.9309G>T p.K3103N | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV59956135; called by muse, mutect2
- TAAR9 | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.013); catalogued as rs1243897152, COSV71512346; called by muse, mutect2, varscan2
- TAF1L | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs748126798, COSV54257964, COSV54261800; called by muse, mutect2
- TANC1 | c.4090G>A p.E1364K | Missense Mutation (SNP) | VAF 70/211 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.227); catalogued as rs779370060, COSV55082392, COSV55082815; called by muse, mutect2, varscan2
- TBC1D14 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 71/202 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV63391571; called by muse, mutect2, varscan2
- TBC1D25 | c.533C>A p.S178Y | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV65123240; called by muse, mutect2, varscan2
- TBC1D7 | c.75G>T p.K25N | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755946421, COSV58243651; called by muse, mutect2, varscan2
- TBX5 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 116/389 reads (30%) | catalogued as CM004661, COSV100090760; called by muse, mutect2, varscan2
- TECTA | c.6377C>A p.S2126Y | Missense Mutation (SNP) | VAF 95/303 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.083); catalogued as COSV50697485; called by muse, mutect2, varscan2
- TENM3 | c.7397C>T p.S2466L | Missense Mutation (SNP) | VAF 83/263 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV69315065; called by muse, mutect2, varscan2
- TEX15 | c.2452C>A p.L818I (on ENST00000256246; = p.L1201I on NM_001350162.2) | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.288); catalogued as COSV56343600, COSV56344605; called by muse, mutect2
- TGM4 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 69/171 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs143965912; called by muse, mutect2, varscan2
- THBS2 | c.2819A>G p.N940S | Missense Mutation (SNP) | VAF 71/208 reads (34%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs200593207, COSV100827905; called by muse, mutect2, varscan2
- THSD7B | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 109/279 reads (39%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.892); catalogued as rs1250652530, COSV55712646; called by muse, mutect2, varscan2
- TLL1 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 118/341 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.846); catalogued as COSV50310379; called by muse, mutect2, varscan2
- TLR4 | c.1962C>A p.F654L (on ENST00000355622 / NM_138554.5; = p.F614L on NM_003266.4) | Missense Mutation (SNP) | VAF 84/214 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.698); catalogued as rs531681113; called by muse, mutect2, varscan2
- TMC1 | c.2050G>A p.D684N | Missense Mutation (SNP) | VAF 40/488 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as rs563322370, CM1512612, COSV52766443; ClinVar: uncertain significance; called by muse, mutect2
- TMEM95 | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 57/192 reads (30%) | catalogued as rs1020245842; called by muse, mutect2, varscan2
- TMTC1 | c.1057C>T p.R353W (on ENST00000539277 / NM_001193451.2; = p.R245W on NM_175861.3) | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770862561, COSV55474854; called by muse, mutect2, varscan2
- TMX2 | c.549-8C>A | Splice Region (SNP) | VAF 36/121 reads (30%) | catalogued as rs1439549877; called by muse, mutect2, varscan2
- TNFSF11 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 150/460 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775440686, COSV53480359; called by muse, varscan2
- TNFSF13B | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 43/141 reads (30%) | catalogued as COSV65515887; called by muse, mutect2, varscan2
- TNFSF15 | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as rs368084272; called by muse, mutect2
- TNRC6C | c.1670C>T p.A557V | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs1009523723; called by muse, mutect2, varscan2
- TOM1L2 | c.979G>A p.E327K (on ENST00000379504 / NM_001350333.2; = p.E277K on NM_001033551.3) | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.311); catalogued as rs757520450, COSV58886298; called by muse, mutect2, varscan2
- TONSL | c.1574G>A p.R525Q | Missense Mutation (SNP) | VAF 76/199 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs749525244; called by muse, mutect2, varscan2
- TOPAZ1 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.066); catalogued as rs1371718823, COSV59075212; called by muse, mutect2
- TPM3 | c.757A>G p.T253A | Missense Mutation (SNP) | VAF 143/419 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as rs1196231253; called by muse, mutect2, varscan2
- TRAPPC8 | c.1341G>T p.K447N | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51966747, COSV99351118; called by muse, mutect2, varscan2
- TRIM26 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.301); catalogued as rs144770536; called by muse, mutect2, varscan2
- TRIM38 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as rs1266712951, COSV62641678; called by muse, mutect2, varscan2
- TRIM69 | c.395T>G p.L132R | Missense Mutation (SNP) | VAF 87/268 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1426803997; called by muse, mutect2, varscan2
- TRIT1 | c.1345G>T p.E449* | Nonsense Mutation (SNP) | VAF 38/146 reads (26%) | catalogued as COSV100381570, COSV100381702; called by muse, mutect2, varscan2
- TRO | c.1492C>T p.R498* | Nonsense Mutation (SNP) | VAF 36/100 reads (36%) | catalogued as rs370685409, COSV99437074; called by muse, mutect2, varscan2
- TRPC1 | c.195G>T p.K65N | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs1219807911; called by muse, mutect2, varscan2
- TRPM3 | c.2230G>A p.V744M (on ENST00000357533 / NM_001366142.2; = p.V587M on NM_020952.6) | Missense Mutation (SNP) | VAF 73/171 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as rs747713615, COSV62579795; called by muse, mutect2, varscan2
- TRPV4 | c.1828C>A p.L610I | Missense Mutation (SNP) | VAF 150/467 reads (32%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.999); catalogued as COSV55681881; called by muse, mutect2, varscan2
- TSPAN18 | c.348C>A p.F116L | Missense Mutation (SNP) | VAF 87/210 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.027); catalogued as COSV60882665; called by muse, mutect2, varscan2
- TTC13 | c.2299C>T p.R767* | Nonsense Mutation (SNP) | VAF 8/90 reads (9%) | catalogued as rs1296857589; called by muse, mutect2
- TTN | c.97430G>A p.R32477Q (on ENST00000591111; = p.R25053Q on NM_003319.4) | Missense Mutation (SNP) | VAF 71/180 reads (39%) | PolyPhen possibly damaging (0.89); catalogued as rs551905996; called by muse, mutect2, varscan2
- TTN | c.95419C>T p.R31807* (on ENST00000591111; = p.R24383* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 37/96 reads (39%) | catalogued as rs1168878579, COSV60119403; called by muse, mutect2, varscan2
- TTN | c.32011G>T p.E10671* (on ENST00000591111; = p.E9744* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 70/191 reads (37%) | catalogued as COSV59998853; called by muse, mutect2, varscan2
- TTN | c.15874G>A p.E5292K (on ENST00000591111; = p.E4365K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/88 reads (36%) | PolyPhen benign (0.374); catalogued as rs374682077; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.5981C>T p.S1994L (on ENST00000591111; = p.S1948L on NM_003319.4) | Missense Mutation (SNP) | VAF 101/274 reads (37%) | PolyPhen possibly damaging (0.683); catalogued as rs758483877, COSV59887888; called by muse, mutect2, varscan2
- TULP2 | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 10/133 reads (8%) | catalogued as COSV55478657; called by muse, mutect2
- UGT2B15 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs377015117; called by muse, mutect2
- UNC13C | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV52849155, COSV52868879; called by muse, mutect2
- USH2A | c.13895C>A p.P4632H | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99048385; called by muse, mutect2, varscan2
- USP16 | c.1364G>A p.R455Q | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs755644897, COSV57625226; called by muse, mutect2, varscan2
- USP16 | c.2060C>A p.S687Y | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV57624224; called by muse, mutect2, varscan2
- USP28 | c.2824G>T p.E942* | Nonsense Mutation (SNP) | VAF 6/92 reads (7%) | catalogued as COSV50157858; called by muse, mutect2
- USP29 | c.1023C>A p.F341L | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV54142385; called by muse, mutect2, varscan2
- USP29 | c.1198G>T p.E400* | Nonsense Mutation (SNP) | VAF 42/133 reads (32%) | catalogued as COSV54140107, COSV54143038; called by muse, mutect2, varscan2
- USP37 | c.37C>T p.R13* | Nonsense Mutation (SNP) | VAF 29/94 reads (31%) | catalogued as rs759153042, COSV104383999; called by muse, varscan2
- USP8 | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.799); catalogued as rs374126671; called by muse, mutect2, varscan2
- UTP14A | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.185); catalogued as rs375022750, COSV64086541; called by muse, mutect2, varscan2
- VANGL2 | c.900G>T p.K300N | Missense Mutation (SNP) | VAF 27/343 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV63604939; called by muse, mutect2
- VPS13C | c.7161G>A p.M2387I (on ENST00000644861 / NM_020821.3; = p.M2344I on NM_017684.5) | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV99827991; called by muse, mutect2, varscan2
- VPS25 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.063); catalogued as rs534684067; called by muse, mutect2, varscan2
- VPS35 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54480323; called by muse, mutect2
- VSIG1 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 85/254 reads (33%) | catalogued as COSV54260043; called by muse, mutect2, varscan2
- WDR35 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs751389404, COSV55600234; called by muse, mutect2, varscan2
- WDR44 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV54165357; called by muse, mutect2
- WDR59 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 131/379 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.719); catalogued as rs1248018071, COSV100049780; called by muse, mutect2, varscan2
- WDR7 | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 15/134 reads (11%) | catalogued as COSV54357919; called by muse, mutect2
- XIAP | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 15/110 reads (14%) | catalogued as COSV63022812; called by muse, mutect2, varscan2
- YIPF6 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs776029090, COSV65855242; called by muse, varscan2
- YKT6 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 40/287 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs780133803, COSV56272711; called by muse, mutect2, varscan2
- ZBTB41 | c.669G>T p.E223D | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV100963394; called by muse, mutect2
- ZBTB8A | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100331462; called by muse, mutect2, varscan2
- ZDBF2 | c.3916G>T p.E1306* | Nonsense Mutation (SNP) | VAF 41/148 reads (28%) | catalogued as COSV100985160; called by muse, mutect2, varscan2
- ZFAT | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 51/135 reads (38%) | catalogued as COSV64740292; called by muse, mutect2, varscan2
- ZFP3 | c.677A>C p.K226T | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.316); catalogued as COSV59582210; called by muse, mutect2, varscan2
- ZFP42 | c.905C>T p.T302M | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.226); catalogued as rs1002401560; called by muse, varscan2
- ZMYND8 | c.2938G>A p.E980K (on ENST00000311275 / NM_001363741.2; = p.E954K on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV53683252; called by muse, mutect2
- ZNF117 | c.496A>G p.K166E | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV51430013; called by muse, mutect2, varscan2
- ZNF180 | c.1706G>T p.R569I | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as rs775083814, COSV55420320, COSV55422657; called by muse, mutect2, varscan2
- ZNF195 | c.1793G>T p.R598I (on ENST00000399602 / NM_001130520.3; = p.R526I on NM_007152.5) | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.983); catalogued as rs1177239872, COSV50001742; called by muse, mutect2, varscan2
- ZNF195 | c.1457G>T p.R486I (on ENST00000399602 / NM_001130520.3; = p.R414I on NM_007152.5) | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.02); catalogued as COSV99137862; called by muse, mutect2, varscan2
- ZNF217 | c.2231G>A p.R744Q | Missense Mutation (SNP) | VAF 68/206 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs551111351, COSV56595367; called by muse, mutect2, varscan2
- ZNF267 | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV56250735, COSV56251800; called by muse, mutect2, varscan2
- ZNF280A | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs751413057, COSV57480816; called by muse, mutect2, varscan2
- ZNF35 | c.1432G>T p.E478* | Nonsense Mutation (SNP) | VAF 17/110 reads (15%) | catalogued as COSV56076360; called by muse, mutect2, varscan2
- ZNF460 | c.1393C>T p.R465* | Nonsense Mutation (SNP) | VAF 48/196 reads (24%) | catalogued as rs1179718453; called by muse, mutect2, varscan2
- ZNF470 | c.743G>T p.R248I | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as rs1243207497, COSV57968691; called by muse, mutect2, varscan2
- ZNF479 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV100482763; called by muse, mutect2, varscan2
- ZNF485 | c.449G>T p.R150I | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as COSV62423903; called by muse, mutect2, varscan2
- ZNF492 | c.566G>T p.R189I | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.043); catalogued as COSV71761780; called by muse, mutect2, varscan2
- ZNF532 | c.2825C>A p.S942Y | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100266777; called by muse, mutect2, varscan2
- ZNF570 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs762128010, COSV100356291; called by muse, mutect2, varscan2
- ZNF578 | c.584G>T p.R195I | Missense Mutation (SNP) | VAF 70/233 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.648); catalogued as COSV69736522; called by muse, mutect2, varscan2
- ZNF578 | c.1306T>G p.F436V | Missense Mutation (SNP) | VAF 20/207 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV69737629; called by muse, mutect2
- ZNF605 | c.1142T>G p.I381S | Missense Mutation (SNP) | VAF 12/261 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as rs1382907955; called by muse, mutect2
- ZNF616 | c.2126G>T p.R709I | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.821); catalogued as rs750634646, COSV57510360; called by muse, mutect2, varscan2
- ZNF649 | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs1184191478, COSV56815612; called by muse, mutect2, varscan2
- ZNF674 | c.1382G>A p.R461K | Missense Mutation (SNP) | VAF 17/212 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.5); catalogued as COSV70378550; called by muse, mutect2
- ZNF682 | c.433T>G p.F145V | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs748462207; called by muse, mutect2, varscan2
- ZNF721 | c.1022G>T p.R341I (on ENST00000338977; = p.R353I on NM_133474.4) | Missense Mutation (SNP) | VAF 67/200 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.983); catalogued as rs781992777, COSV100167538, COSV59088971; called by muse, mutect2, varscan2
- ZNF780B | c.1695C>A p.F565L | Missense Mutation (SNP) | VAF 112/312 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as rs1250072925, COSV55467018; called by muse, mutect2, varscan2
- ZNF814 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 52/308 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs771516975; called by muse, varscan2
- ZNF841 | c.2258G>A p.R753Q (on ENST00000426391 / NM_001369830.1; = p.R869Q on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as rs535615577, COSV100744597; called by muse, mutect2, varscan2
- ABCC12 | c.3614T>C p.V1205A | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- ACAP1 | c.531C>A p.I177= | Splice Region (SNP) | VAF 26/67 reads (39%) | called by muse, mutect2, varscan2
- ACSM1 | c.1712A>C p.K571T | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- ACTR10 | c.1227G>T p.M409I | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ACVRL1 | c.1294G>T p.D432Y | Missense Mutation (SNP) | VAF 116/334 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADD3 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 44/159 reads (28%) | called by muse, mutect2, varscan2
- AFM | c.1118T>C p.I373T | Missense Mutation (SNP) | VAF 61/177 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- AGGF1 | c.1689G>T p.K563N | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- AHNAK | c.17464T>G p.F5822V | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- AHNAK | c.11982G>T p.M3994I | Missense Mutation (SNP) | VAF 75/218 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- AKAP3 | c.1402G>T p.E468* | Nonsense Mutation (SNP) | VAF 78/218 reads (36%) | called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.4116A>C p.K1372N | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- ANKRD10 | c.631A>C p.N211H | Missense Mutation (SNP) | VAF 81/208 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- ANKRD12 | c.611T>G p.L204* | Nonsense Mutation (SNP) | VAF 10/184 reads (5%) | called by muse, mutect2
- ANKRD22 | c.535A>C p.K179Q | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- ANKRD50 | c.3806A>C p.K1269T | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ANKS4B | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 103/247 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- APOB | c.1465C>A p.L489M | Missense Mutation (SNP) | VAF 130/367 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AQP2 | c.526-2A>G p.X176_splice | Splice Site (SNP) | VAF 140/393 reads (36%) | called by muse, mutect2, varscan2
- ARHGAP18 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 24/171 reads (14%) | called by muse, mutect2
- ARHGAP27 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 111/291 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- ARHGAP35 | c.1052T>G p.L351R | Missense Mutation (SNP) | VAF 67/162 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGDIB | c.340A>C p.K114Q | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ARID5B | c.1489dup p.I497Nfs*31 | Frame Shift Ins (INS) | VAF 48/137 reads (35%) | called by mutect2, varscan2
- ARPC5L | c.68T>G p.F23C | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, varscan2
- ASPA | c.85T>G p.F29V | Missense Mutation (SNP) | VAF 137/310 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ASPDH | c.529G>A p.E177K (on ENST00000389208 / NM_001114598.2; = p.E72K on NM_001024656.3) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ASPM | c.2020A>C p.K674Q | Missense Mutation (SNP) | VAF 84/241 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- ATL2 | c.431A>C p.E144A | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- ATM | c.90T>G p.F30L | Missense Mutation (SNP) | VAF 36/308 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ATXN2L | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.314); called by muse, mutect2
- BPIFA1 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- C12orf50 | c.875G>T p.W292L | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); called by muse, mutect2
- C16orf96 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- C2orf81 | c.1517A>G p.D506G | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- CACNA1B | c.5731T>C p.F1911L | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2
- CAGE1 | c.1555T>G p.L519V (on ENST00000512086; = p.L383V on NM_205864.3) | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- CCDC110 | c.2022G>T p.E674D | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- CCDC141 | c.1636G>T p.E546* | Nonsense Mutation (SNP) | VAF 42/153 reads (27%) | called by muse, mutect2, varscan2
- CCDC168 | c.17827A>G p.N5943D | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- CCDC168 | c.4636G>T p.E1546* | Nonsense Mutation (SNP) | VAF 61/186 reads (33%) | called by muse, mutect2, varscan2
- CCDC175 | c.1060C>G p.R354G | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- CCDC7 | c.3451T>G p.F1151V | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CCN4 | c.461C>T p.T154I | Missense Mutation (SNP) | VAF 107/301 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CDH11 | c.579T>G p.N193K | Missense Mutation (SNP) | VAF 89/258 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- CDH7 | c.952A>G p.T318A | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- CDH9 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, varscan2
- CDKL5 | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 117/342 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEBPZ | c.2908T>G p.L970V | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CENPF | c.5352G>T p.L1784F | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CEP44 | c.118T>G p.L40V | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- CERKL | c.1665G>T p.M555I (on ENST00000339098 / NM_001030311.2; = p.M529I on NM_201548.5) | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CFAP36 | c.533A>C p.K178T | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- CHD3 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 67/233 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); called by muse, varscan2
- CHD7 | c.2295C>A p.F765L | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- CHMP1B | c.340T>G p.L114V | Missense Mutation (SNP) | VAF 39/350 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CLDN34 | c.258T>G p.I86M | Missense Mutation (SNP) | VAF 103/274 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CMAS | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 43/164 reads (26%) | called by muse, varscan2
- CMC2 | c.77A>G p.K26R | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- CMTR2 | c.2004C>A p.F668L | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CMYA5 | c.8267A>G p.D2756G | Missense Mutation (SNP) | VAF 21/193 reads (11%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTNAP1 | c.274A>C p.N92H | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- CPA6 | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 51/117 reads (44%) | called by muse, mutect2, varscan2
- CPS1 | c.4150G>T p.E1384* | Nonsense Mutation (SNP) | VAF 18/238 reads (8%) | called by muse, mutect2
- CPXCR1 | c.254T>G p.L85R | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CPXM2 | c.893C>A p.P298H | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by mutect2, varscan2
- CR2 | c.2952G>T p.L984F | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- CSNK2B | c.72+2T>G p.X24_splice | Splice Site (SNP) | VAF 96/263 reads (37%) | called by muse, mutect2, varscan2
- CUBN | c.10309T>G p.F3437V | Missense Mutation (SNP) | VAF 97/288 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DARS1 | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 23/110 reads (21%) | called by muse, mutect2, varscan2
- DAZL | c.740C>A p.S247Y | Missense Mutation (SNP) | VAF 112/318 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DCUN1D4 | c.383T>G p.F128C | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DCX | c.309C>A p.Y103* | Nonsense Mutation (SNP) | VAF 69/201 reads (34%) | called by muse, mutect2, varscan2
- DDB1 | c.218G>A p.S73N | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- DICER1 | c.3892C>A p.L1298I | Missense Mutation (SNP) | VAF 77/384 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by muse, varscan2
- DLD | c.704T>G p.L235R | Missense Mutation (SNP) | VAF 96/255 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DLG2 | c.823A>C p.K275Q | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- DMGDH | c.2561G>T p.R854I | Missense Mutation (SNP) | VAF 124/370 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); called by muse, varscan2
- DMXL1 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 15/109 reads (14%) | called by muse, mutect2, varscan2
- DNAH12 | c.854T>G p.L285W | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- DNAH14 | c.2744T>G p.I915S (on ENST00000445597; = p.I981S on NM_001367479.1) | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.058); called by muse, mutect2
- DNAH17 | c.7072G>A p.A2358T | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- DNAH6 | c.12404T>C p.L4135P | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- DNAH8 | c.10094T>A p.I3365N | Missense Mutation (SNP) | VAF 61/183 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- DNAH9 | c.11666C>A p.S3889* | Nonsense Mutation (SNP) | VAF 20/202 reads (10%) | called by muse, mutect2
- DNTT | c.594G>T p.L198F | Missense Mutation (SNP) | VAF 16/215 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- DOCK10 | c.549C>A p.F183L | Missense Mutation (SNP) | VAF 54/209 reads (26%) | SIFT tolerated (1); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- DST | c.8321A>C p.N2774T | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- DYNC2H1 | c.9665G>T p.R3222I | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYSF | c.1372A>C p.K458Q | Missense Mutation (SNP) | VAF 137/414 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- EFCAB13 | c.548A>C p.K183T | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- EFCAB13 | c.2884G>A p.A962T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- EFCAB5 | c.2910T>G p.I970M | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.059); called by muse, mutect2
- EFHB | c.1870A>C p.N624H | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- EFHB | c.152A>C p.N51T | Missense Mutation (SNP) | VAF 30/452 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2
- EML5 | c.1289G>A p.S430N | Missense Mutation (SNP) | VAF 77/248 reads (31%) | SIFT tolerated (0.99); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ENPP1 | c.1141T>G p.S381A | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EPGN | c.148G>T p.G50* | Nonsense Mutation (SNP) | VAF 15/99 reads (15%) | called by muse, mutect2, varscan2
- EPHX4 | c.926T>G p.F309C | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ERVW-1 | c.1529C>T p.S510F | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- F8 | c.696G>T p.K232N | Missense Mutation (SNP) | VAF 46/337 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM122B | c.134G>T p.R45I | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- FAM13A | c.759+5G>A | Splice Region (SNP) | VAF 31/88 reads (35%) | called by muse, mutect2, varscan2
- FAM71E1 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, varscan2
- FAM8A1 | c.1226G>T p.R409I | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- FAM9A | c.328G>T p.D110Y | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FBXL14 | c.1112A>C p.K371T | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FGD1 | c.1645G>C p.E549Q | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- FOXP2 | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 107/314 reads (34%) | called by muse, mutect2, varscan2
- FREM3 | c.4896C>A p.F1632L | Missense Mutation (SNP) | VAF 11/260 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2
- G6PC2 | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 18/383 reads (5%) | called by muse, mutect2
- GALNT13 | c.513A>C p.K171N | Missense Mutation (SNP) | VAF 78/222 reads (35%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- GALNT13 | c.1670G>T p.*557Lext*39 | Nonstop Mutation (SNP) | VAF 21/75 reads (28%) | called by muse, mutect2, varscan2
- GBP1 | c.548G>A p.R183K | Missense Mutation (SNP) | VAF 138/434 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GBP7 | c.1743A>C p.Q581H | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- GCNT4 | c.1176T>G p.I392M | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GFRA1 | c.1012C>T p.L338F | Missense Mutation (SNP) | VAF 116/321 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GGH | c.607-1G>T p.X203_splice | Splice Site (SNP) | VAF 28/58 reads (48%) | called by muse, mutect2, varscan2
- GHR | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.141); called by muse, mutect2
- GJA8 | c.322A>C p.S108R | Missense Mutation (SNP) | VAF 80/203 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- GK | c.1623dup p.I542Yfs*4 (on ENST00000427190 / NM_001205019.2; = p.I536Yfs*4 on NM_001128127.2) | Frame Shift Ins (INS) | VAF 110/314 reads (35%) | called by mutect2, pindel, varscan2
- GLUD1 | c.1344T>G p.H448Q | Missense Mutation (SNP) | VAF 13/392 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GLYATL1 | c.786T>G p.F262L (on ENST00000317391 / NM_001354699.1; = p.F293L on NM_080661.4) | Missense Mutation (SNP) | VAF 98/282 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- GOLGB1 | c.435A>C p.E145D | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.513); called by muse, mutect2
- GOLGB1 | c.285dup p.L96Tfs*14 | Frame Shift Ins (INS) | VAF 25/88 reads (28%) | called by mutect2, pindel, varscan2
- GPATCH2L | c.1142T>C p.V381A | Missense Mutation (SNP) | VAF 64/199 reads (32%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- GRAMD1B | c.6A>C p.K2N | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- GREB1 | c.5642C>T p.S1881F | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRID2 | c.1870C>A p.P624T | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GRIN2B | c.2400T>G p.I800M | Missense Mutation (SNP) | VAF 102/240 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GTPBP2 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); called by muse, mutect2
- GUCA2B | c.314A>G p.N105S | Missense Mutation (SNP) | VAF 83/263 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HERC2 | c.184A>T p.K62* | Nonsense Mutation (SNP) | VAF 30/100 reads (30%) | called by muse, mutect2, varscan2
- HIVEP2 | c.1343C>G p.A448G | Missense Mutation (SNP) | VAF 34/259 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- HROB | c.169T>C p.S57P | Missense Mutation (SNP) | VAF 86/253 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- HSF5 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 86/251 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- HTR1F | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HYDIN | c.10654G>T p.V3552L | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.006); called by muse, mutect2
- HYPK | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.964); called by muse, mutect2
- IDUA | c.1755C>A p.F585L | Missense Mutation (SNP) | VAF 121/330 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- IGSF10 | c.3913G>T p.D1305Y | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- IGSF3 | c.1055C>A p.A352D | Missense Mutation (SNP) | VAF 17/242 reads (7%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.481); called by muse, mutect2
- IL12RB2 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 106/285 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- IL1RAPL1 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IL1RAPL2 | c.661A>T p.K221* | Nonsense Mutation (SNP) | VAF 35/95 reads (37%) | called by muse, mutect2, varscan2
- IL20RA | c.1623C>A p.F541L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- IL21R | c.1425G>T p.E475D | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL6ST | c.192C>A p.Y64* | Nonsense Mutation (SNP) | VAF 8/140 reads (6%) | called by muse, mutect2
- INPPL1 | c.183-1G>T p.X61_splice | Splice Site (SNP) | VAF 45/143 reads (31%) | called by muse, mutect2, varscan2
- INTS6 | c.1669A>C p.T557P | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); called by muse, mutect2
- IPO9 | c.32C>G p.S11C | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- IRX5 | c.1317C>A p.F439L | Missense Mutation (SNP) | VAF 68/220 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ITGA6 | c.1706A>C p.K569T (on ENST00000442250; = p.K530T on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/327 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- ITGB3BP | c.422A>C p.E141A | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.277); called by muse, mutect2
- JADE3 | c.2353G>T p.E785* | Nonsense Mutation (SNP) | VAF 66/201 reads (33%) | called by muse, mutect2, varscan2
- JAK1 | c.1097T>G p.F366C | Missense Mutation (SNP) | VAF 60/204 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- JAKMIP3 | c.2508C>A p.F836L | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- JAM3 | c.612+4A>C | Splice Region (SNP) | VAF 113/351 reads (32%) | called by muse, mutect2, varscan2
- KANK4 | c.904G>T p.E302* | Nonsense Mutation (SNP) | VAF 51/141 reads (36%) | called by muse, mutect2, varscan2
- KBTBD3 | c.1035C>A p.F345L | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNH5 | c.59T>G p.V20G | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- KCNIP1 | c.515A>G p.Y172C (on ENST00000411494 / NM_001034837.3; = p.Y161C on NM_014592.4) | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.027); called by muse, varscan2
- KCNIP4 | c.260T>G p.L87R | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- KCNJ2 | c.518C>A p.A173D | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- KCNJ3 | c.1276A>C p.K426Q | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.261); called by muse, mutect2
- KDM3A | c.3778G>A p.V1260M | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA0408 | c.1801T>A p.L601I | Missense Mutation (SNP) | VAF 101/290 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- KIF1B | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 38/330 reads (12%) | called by muse, mutect2, varscan2
- KMT2B | c.2389A>G p.K797E | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- KMT2D | c.8631C>A p.F2877L | Missense Mutation (SNP) | VAF 48/463 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- KPNA3 | c.1552G>T p.E518* | Nonsense Mutation (SNP) | VAF 66/152 reads (43%) | called by muse, varscan2
- KRTAP9-4 | c.308G>T p.R103I | Missense Mutation (SNP) | VAF 81/728 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LANCL3 | c.603T>G p.I201M | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- LCTL | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LDB2 | c.27C>A p.F9L | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- LGSN | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 30/111 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- LILRB2 | c.1040C>A p.S347* | Nonsense Mutation (SNP) | VAF 110/313 reads (35%) | called by muse, mutect2, varscan2
- LPAR3 | c.503A>C p.N168T | Missense Mutation (SNP) | VAF 75/214 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LRRC37A3 | c.4205T>G p.F1402C | Missense Mutation (SNP) | VAF 174/505 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- LRRC39 | c.533T>G p.L178R | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRD1 | c.970G>T p.E324* | Nonsense Mutation (SNP) | VAF 24/72 reads (33%) | called by muse, mutect2, varscan2
- LRRK2 | c.5294T>G p.I1765S | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- LTN1 | c.2138A>C p.N713T | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- LUZP4 | c.817C>T p.L273F | Missense Mutation (SNP) | VAF 115/388 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- LY75 | c.1684G>T p.D562Y | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LYST | c.8869C>T p.R2957* | Nonsense Mutation (SNP) | VAF 138/406 reads (34%) | called by muse, mutect2, varscan2
- MACC1 | c.1418C>A p.S473Y | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2
- MAP3K19 | c.1186G>T p.E396* | Nonsense Mutation (SNP) | VAF 59/186 reads (32%) | called by muse, mutect2, varscan2
- MATN2 | c.868T>C p.C290R | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- MBOAT2 | c.1451A>C p.K484T | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- METTL21C | c.476A>C p.Q159P | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- MORC1 | c.2015G>T p.R672I | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MORC1 | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- MPV17 | c.50A>C p.K17T | Missense Mutation (SNP) | VAF 32/310 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MRC1 | c.2302A>C p.N768H | Missense Mutation (SNP) | VAF 121/350 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- MRC1 | c.3650-1G>A p.X1217_splice | Splice Site (SNP) | VAF 135/358 reads (38%) | called by muse, mutect2, varscan2
- MSR1 | c.110A>C p.K37T | Missense Mutation (SNP) | VAF 99/312 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- MTM1 | c.774G>T p.E258D | Missense Mutation (SNP) | VAF 44/266 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- MTR | c.2734G>A p.E912K | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- MTRES1 | c.628A>C p.K210Q | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
536 further variants in this file (182 protein-altering or splice-affecting, 193 silent, 161 other) are not listed here.
